Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6465, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6465-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED] Case ID	[REDACTED] Subject ID	Formatted Path Report
[REDACTED]	[REDACTED]	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Abdominal perineal resection Specimen size: Not specified Tumor site: Rectosigmoid junction Tumor size: 7.5 x 0 x 7.2 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Perirectal tissues Lymph nodes: 0/12 positive for metastasis (Adjacent fatty tissue 0/12) Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 800ec290-2f76-4cf1-8e87-8428b8de2046 (TCGA-F5-6465.43E9A5D1-BF99-4768-985A-13C5E319882B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).